Gene-level copy-number profile of specimen HCM-CSHL-0668-C18-85A from HCMI case HCM-CSHL-0668-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 48.4 years (17,670 days).
Specimen HCM-CSHL-0668-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 13bc2f59-bb5e-4132-a56c-cc494099943f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0668-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/3265d1e5-6a08-4041-99cc-6a093d24122a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 22; copy number 2: 20,490; copy number 3: 9,059; copy number 4: 19,911; copy number 5: 5,559; copy number 6: 3,135; copy number 7: 126; copy number 9: 61; copy number 13: 19.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,109 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–148,446,299, 2,697 genes, copy number 6–13 (broad region; genes not listed).
- chr7:148,807,383–159,233,377, 222 genes, copy number 6 (broad region; genes not listed).
- chr8:7,355,517–7,385,558, 2 genes, copy number 5: ZNF705G, DEFB108C.
- chr8:32,911,493–32,911,598, 1 gene, copy number 7: RNU6-663P.
- chr8:36,987,977–138,083,657, 1,455 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:139,096,305–145,066,685, 208 genes, copy number 5 (broad region; genes not listed).
- chr12:63,779,842–72,186,618, 185 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:119,593,774–123,585,115, 156 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:124,324,415–125,662,377, 30 genes, copy number 5: NCOR2, MIR6880, AC073916.1, AC073592.1, AC073592.7, AC073592.3, AC073592.9, AC073592.5, AC073592.6, AC073592.8, AC073592.2, AC073592.10, AC073592.4, AC073593.1, SCARB1, AC073593.2, RNU6-927P, UBC, MIR5188, RPL22P19, DHX37, BRI3BP, THRIL, AC122688.1, AACS, AC122688.3, AC122688.2, AC122688.4, TMEM132B, AC093028.1.
- chr14:22,415,362–22,423,042, 2 genes, copy number 7 (within-gene range 2–7): AC244502.3, TRDV2.
- chr15:76,347,904–77,037,475, 8 genes, copy number 5: SCAPER, AC090751.1, MIR3713, RN7SKP217, RCN2, RN7SL278P, KRT8P23, PSTPIP1.
- chr15:77,100,656–77,534,110, 6 genes, copy number 5: PEAK1, AC087465.1, AC060773.1, HMG20A, AC090984.1, AC046168.1.
- chr15:84,053,113–87,029,052, 82 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr15:94,033,658–94,034,177, 1 gene, copy number 5 (within-gene range 3–5): AC104390.1.
- chr15:95,990,582–101,979,093, 151 genes, copy number 5 (broad region; genes not listed).
- chr18:45,034–12,776,140, 285 genes, copy number 5 (broad region; genes not listed).
- chr20:30,278,906–41,712,600, 318 genes, copy number 5 (broad region; genes not listed).
- chr20:42,072,752–64,327,972, 548 genes, copy number 5 (broad region; genes not listed).
- chr21:7,744,962–8,603,984, 27 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68.
- chr21:10,482,738–39,802,096, 512 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:41,141,493–46,691,226, 209 genes, copy number 5 (broad region; genes not listed).
- chr22:18,400,407–18,512,187, 4 genes, copy number 7: PPP1R26P3, FAM230A, AC023490.2, FAM247B.

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
